Somatic mutation profile of tumor specimen 0E0840 from CCDI case PBCUNJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0840: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b47d5a8b-99b9-4cd4-92a4-50c02de98e73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E084D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aaa82d2d-4840-4765-81e2-f33092102749

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'Flank 1, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOCT | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 134/1235 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- PIP5KL1 | c.560-4C>T | Splice Region (SNP) | VAF 109/975 reads (11%) | called by muse, mutect2, varscan2
- TONSL | c.4079C>G p.P1360R | Missense Mutation (SNP) | VAF 92/705 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SRRM2 | c.31C>A p.R11= | Silent (SNP) | VAF 180/396 reads (45%) | catalogued as COSV57068426; called by muse, varscan2
- R3HCC1 | chr8:23296127 C>T | 3'Flank (SNP) | VAF 114/233 reads (49%) | catalogued as rs753619888; called by muse, mutect2, varscan2
